Somatic mutation profile of tumor specimen MP2PRT-PATMZW-TMP1-A (aliquot MP2PRT-PATMZW-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATMZW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.4 years (4,531 days).
Specimen MP2PRT-PATMZW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec174ce7-9d57-42df-a7fa-8ba284c464ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATMZW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATMZW-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/849e4a2d-e569-42aa-b269-f14b4fb76e06

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 81/381 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.2794C>T p.R932W (on ENST00000280772 / NM_001320874.2; = p.R66W on NM_001149.3) | Missense Mutation (SNP) | VAF 67/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771103668; called by muse, mutect2, varscan2
- EBF3 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62474506; called by muse, mutect2, varscan2
- FREM2 | c.3328C>T p.P1110S | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as rs1236518847, COSV99751199; called by muse, mutect2, varscan2
- IGHV3-11 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 16/535 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.468); catalogued as rs782646160; called by muse, mutect2
- KCNE4 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 98/475 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs777074947; called by muse, mutect2
- MS4A1 | c.687_689del p.L230del | In Frame Del (DEL) | VAF 32/101 reads (32%) | catalogued as rs1565195820; called by mutect2, pindel, varscan2
- TGIF2LY | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs752369378; called by muse, mutect2, varscan2
- TMC7 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs1355238435, COSV58583514; called by muse, mutect2, varscan2
- VWA3B | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1163716972; called by muse, mutect2, varscan2
- ZNF462 | c.3371G>A p.R1124Q | Missense Mutation (SNP) | VAF 86/436 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs1363698209; called by muse, mutect2, varscan2
- ASIC2 | c.1462C>A p.H488N | Missense Mutation (SNP) | VAF 68/430 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SACS | c.4685_4686insCCCCT p.V1563Pfs*13 | Frame Shift Ins (INS) | VAF 32/176 reads (18%) | called by pindel, varscan2
- SACS | c.4679T>C p.F1560S | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, varscan2
- SLC15A2 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- TLCD1 | c.4_7dup p.R3Pfs*70 | Frame Shift Ins (INS) | VAF 84/539 reads (16%) | called by pindel, varscan2
- FLG | c.11877A>G p.Q3959= | Silent (SNP) | VAF 71/353 reads (20%) | catalogued as rs780476362, COSV64237960; called by muse, mutect2, varscan2
- FMN2 | c.3513G>A p.A1171= | Silent (SNP) | VAF 38/173 reads (22%) | catalogued as rs775315994; called by muse, mutect2, varscan2
- SACS | c.4680T>C p.F1560= | Silent (SNP) | VAF 33/172 reads (19%) | called by muse, varscan2
- SCART1 | c.486G>T p.L162= | Silent (SNP) | VAF 128/1037 reads (12%) | called by muse, mutect2, varscan2
